Somatic mutation profile of tumor specimen TCGA-A7-A6VX-01A (aliquot TCGA-A7-A6VX-01A-12D-A33E-09) from TCGA case TCGA-A7-A6VX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.6 years (25,066 days).
Specimen TCGA-A7-A6VX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d50d383-7444-4288-8e82-bf726ab5aae5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A7-A6VX-10A (Blood Derived Normal), aliquot TCGA-A7-A6VX-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e10420ac-d0b9-4094-b4c0-3284e9665194

The open-access MAF lists 133 somatic variants for this specimen: 107 protein-altering or splice-affecting, 22 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 22, Nonsense Mutation 9, Frame Shift Del 5, Splice Site 3, In Frame Del 2, Intron 2, 5'UTR 1, Splice Region 1, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 16/21 reads (76%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 24/46 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1064794311, CM973401, COSV52661102, COSV52687307, COSV99402633; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAP3 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100686712; called by muse, mutect2
- ADAM19 | c.81G>C p.E27D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99978238; called by muse, varscan2
- AGL | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV99649928; called by muse, mutect2, varscan2
- ARHGEF5 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.166); catalogued as COSV99283136, COSV99283154; called by muse, mutect2, varscan2
- ATP13A2 | c.833C>G p.T278S | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as COSV100454388; called by muse, mutect2, varscan2
- BCAN | c.2149C>G p.R717G | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100228422; called by muse, mutect2, varscan2
- CCDC158 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV101187351; called by muse, mutect2, varscan2
- CIAO2A | c.87G>T p.Q29H | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.28); catalogued as COSV99976381; called by muse, mutect2, varscan2
- CLCN6 | c.1685T>C p.M562T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100412149; called by muse, mutect2, varscan2
- COL4A6 | c.3191T>C p.L1064P | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.25); catalogued as COSV100564922; called by muse, mutect2, varscan2
- CPNE5 | c.633-1G>C p.X211_splice | Splice Site (SNP) | VAF 44/133 reads (33%) | catalogued as rs1015526451, COSV99783228; called by muse, mutect2, varscan2
- CSF3 | c.598G>A p.V200I | Missense Mutation (SNP) | VAF 57/71 reads (80%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1321986970, COSV56641328; called by muse, mutect2, varscan2
- CSMD1 | c.1372T>G p.F458V (on ENST00000520002; = p.F457V on NM_033225.6) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV101224361; called by muse, mutect2, varscan2
- DENND2C | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101283968; called by muse, mutect2
- DNAH1 | c.4132G>C p.E1378Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101326879, COSV101327425; called by muse, mutect2, varscan2
- EEF2 | c.1130C>T p.P377L | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1377534088, COSV100500960; called by muse, mutect2, varscan2
- EGFR | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs532655845, COSV99294439; called by muse, mutect2, varscan2
- EPHX1 | c.1344C>A p.F448L | Missense Mutation (SNP) | VAF 38/278 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55302219, COSV99689178; called by muse, varscan2
- ERMARD | c.439G>C p.E147Q | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100824902; called by muse, mutect2
- FOXC1 | c.1628C>T p.S543F | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101083344; called by muse, mutect2
- FRMPD3 | c.1442G>A p.C481Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776760327, COSV99346934; called by muse, mutect2, varscan2
- FYB1 | c.1940G>C p.G647A (on ENST00000351578 / NM_199335.5; = p.G693A on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as COSV100686186; called by muse, mutect2, varscan2
- GALNT3 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101205000; called by muse, mutect2, varscan2
- GALNT8 | c.931C>G p.R311G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.097); catalogued as COSV52895415, COSV99363168; called by muse, mutect2, varscan2
- GARNL3 | c.1090G>C p.V364L | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV100150622; called by muse, mutect2, varscan2
- GLDC | c.2879G>A p.W960* | Nonsense Mutation (SNP) | VAF 64/106 reads (60%) | catalogued as rs1410625190, COSV100394504; called by muse, mutect2, varscan2
- GPR158 | c.754C>G p.R252G | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as COSV100894205, COSV66268967, COSV66282379; called by muse, mutect2, varscan2
- GRIA1 | c.2579C>A p.P860H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.254); catalogued as COSV99601905; called by muse, mutect2, varscan2
- GSDMA | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as rs201419735, COSV100053801; called by muse, mutect2, varscan2
- IGKV3-20 | c.149G>T p.S50I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs11546122; called by muse, mutect2
- IGSF9B | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.377); catalogued as rs1041177681, COSV100317088, COSV100318293; called by muse, mutect2, varscan2
- ITIH4 | c.2005C>A p.Q669K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99819793; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.251); catalogued as rs952721950, COSV101198222; called by muse, mutect2, varscan2
- JADE3 | c.1402C>T p.R468* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV54466607; called by muse, mutect2, varscan2
- JADE3 | c.1403G>C p.R468P | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99510205; called by muse, mutect2, varscan2
- KIF27 | c.2091G>T p.K697N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99927245; called by mutect2, varscan2
- KMT2C | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100075838; called by muse, mutect2, varscan2
- LRFN2 | c.1591G>C p.G531R | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599878; called by muse, mutect2, varscan2
- LRRC34 | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 61/420 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV100336431; called by muse, mutect2, varscan2
- MAGEE1 | c.2198C>G p.S733* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100819504; called by muse, mutect2, varscan2
- MAN2A2 | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV100847807, COSV100847971; called by muse, mutect2, varscan2
- MARK2 | c.2144G>A p.R715H (on ENST00000402010 / NM_001039469.2; = p.R651H on NM_004954.5) | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV56850418; called by muse, mutect2
- MKI67 | c.6505G>A p.D2169N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.642); catalogued as COSV100896920; called by muse, mutect2, varscan2
- MXD3 | c.497C>G p.S166* | Nonsense Mutation (SNP) | VAF 33/170 reads (19%) | catalogued as COSV100293707; called by muse, mutect2, varscan2
- MYO7A | c.4404G>C p.L1468F | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101289254; called by muse, mutect2, varscan2
- NAALAD2 | c.252G>C p.K84N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as COSV100428739; called by muse, mutect2, varscan2
- NDUFA9 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99866018; called by muse, mutect2, varscan2
- NDUFAF3 | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100455158, COSV58245846; called by muse, mutect2, varscan2
- NEB | c.9371A>G p.N3124S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs781444361, COSV99427034; called by muse, mutect2, varscan2
- NECAP1 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 37/200 reads (19%) | catalogued as COSV100331637; called by muse, mutect2, varscan2
- NEURL1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100872820; called by muse, mutect2, varscan2
- OR10J1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV101419986; called by muse, mutect2, varscan2
- OR2T27 | c.814A>G p.K272E | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.83); catalogued as COSV100788364; called by muse, mutect2, varscan2
- OTOA | c.406A>C p.K136Q | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.086); catalogued as COSV99625611; called by muse, mutect2, varscan2
- PCDH15 | c.4535G>T p.G1512V (on ENST00000644397 / NM_001354429.2; = p.D1473Y on NM_001142770.3) | Missense Mutation (SNP) | VAF 47/257 reads (18%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.696); catalogued as COSV100905441; called by muse, mutect2, varscan2
- PCDHA5 | c.1570C>G p.H524D | Missense Mutation (SNP) | VAF 64/224 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV100972504, COSV65357081; called by muse, mutect2, varscan2
- PCGF6 | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); catalogued as COSV100462262; called by muse, mutect2, varscan2
- PDE3B | c.2460G>T p.M820I | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99963132; called by muse, mutect2, varscan2
- PELP1 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV99343301; called by muse, mutect2, varscan2
- PEX5L | c.758G>T p.S253I | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV99829749; called by muse, mutect2, varscan2
- PHF24 | c.746C>A p.A249D | Missense Mutation (SNP) | VAF 30/287 reads (10%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.663); catalogued as COSV99646247; called by muse, mutect2, varscan2
- PITPNM1 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100039462; called by muse, mutect2, varscan2
- PLCL2 | c.2996A>C p.K999T (on ENST00000615277 / NM_001144382.2; = p.K873T on NM_015184.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV101196949; called by muse, mutect2, varscan2
- PPFIA1 | c.632A>T p.N211I | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV99557956; called by muse, mutect2, varscan2
- PRKDC | c.2706A>T p.K902N | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58042677; called by muse, mutect2, varscan2
- PTK7 | c.2238G>A p.M746I | Missense Mutation (SNP) | VAF 73/156 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV57848905; called by muse, mutect2, varscan2
- PTPN1 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 53/103 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV99247061; called by muse, mutect2, varscan2
- RAPSN | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs200695559, COSV100100371; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RING1 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs536553738, COSV63002405; called by muse, mutect2, varscan2
- RNASEH2B | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as COSV100352408; called by muse, mutect2, varscan2
- RYR3 | c.7725T>A p.D2575E (on ENST00000389232; = p.D2576E on NM_001036.6) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV101214087; called by muse, mutect2, varscan2
- SBF1 | c.3908A>C p.K1303T | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV100817991; called by muse, mutect2, varscan2
- SH2D1A | c.201+2T>G p.X67_splice | Splice Site (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100758355; called by muse, mutect2, varscan2
- SIRT4 | c.205T>G p.S69A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99177468; called by muse, mutect2, varscan2
- SLC38A10 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs1286088699, COSV99917840; called by muse, mutect2, varscan2
- SLC39A6 | c.2047G>A p.E683K | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.115); catalogued as rs1388574792, COSV52369525, COSV99309444, COSV99309873; called by muse, mutect2, varscan2
- SPP1 | c.696C>G p.D232E (on ENST00000395080 / NM_001040058.2; = p.D218E on NM_000582.2) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.191); catalogued as COSV99421209; called by muse, mutect2, varscan2
- STAT3 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99233119; called by muse, mutect2, varscan2
- TAS2R20 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101115487; called by muse, mutect2, varscan2
- TBCC | c.942C>A p.N314K | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99774014; called by muse, mutect2, varscan2
- TECTA | c.3632C>A p.T1211N | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99881284; called by muse, mutect2, varscan2
- TENM1 | c.2152G>T p.G718* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100950719; called by muse, mutect2, varscan2
- THRAP3 | c.953G>A p.G318D | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.215); catalogued as COSV100663562; called by muse, mutect2, varscan2
- TMEM273 | c.241A>C p.T81P | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as COSV100939724; called by muse, mutect2, varscan2
- TRABD2A | c.1261A>G p.K421E (on ENST00000409520 / NM_001277053.2; = p.K372E on NM_001080824.3) | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs1432816119, COSV99408391; called by muse, mutect2, varscan2
- TRAF7 | c.1429G>T p.A477S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100399797; called by muse, mutect2, varscan2
- TWNK | c.458A>G p.E153G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV99273111; called by muse, mutect2
- UPF2 | c.1538C>G p.S513* | Nonsense Mutation (SNP) | VAF 29/84 reads (35%) | catalogued as COSV100707421; called by muse, mutect2, varscan2
- USP2 | c.1239T>C p.D413= | Splice Region (SNP) | VAF 38/115 reads (33%) | catalogued as COSV99489918; called by muse, mutect2, varscan2
- VCAM1 | c.1157C>G p.T386S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.048); catalogued as COSV99658858; called by muse, mutect2, varscan2
- VPS13D | c.3030G>C p.Q1010H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99169220; called by muse, mutect2, varscan2
- ZC3H12B | c.2150A>G p.Q717R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100161941; called by muse, mutect2
- ZNF318 | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100546462; called by muse, mutect2, varscan2
- ZNF497 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99568608; called by muse, mutect2
- ZNFX1 | c.2372G>C p.G791A | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV100870995; called by muse, mutect2, varscan2
- AKAP13 | c.3291_3301delinsT p.Q1098Lfs*16 | Frame Shift Del (DEL) | VAF 34/82 reads (41%) | called by pindel, varscan2*
- CARMIL3 | c.683_703del p.X228_splice | Splice Site (DEL) | VAF 47/250 reads (19%) | called by mutect2, pindel, varscan2
- GBX1 | c.548_563del p.K183Mfs*49 | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- KLHL12 | c.327_337del p.A110Sfs*11 | Frame Shift Del (DEL) | VAF 30/233 reads (13%) | called by mutect2, pindel, varscan2
- OGFOD1 | c.267_268del p.H89Qfs*4 | Frame Shift Del (DEL) | VAF 43/55 reads (78%) | called by pindel*, varscan2
- PIAS3 | c.1709_1723del p.L570_A574del | In Frame Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- PRKAB1 | c.260dup p.G88Rfs*15 | Frame Shift Ins (INS) | VAF 77/130 reads (59%) | called by mutect2, pindel, varscan2
- SEC31A | c.2228_2230del p.G743del (on ENST00000355196 / NM_001318120.1; = p.G704del on NM_016211.4) | In Frame Del (DEL) | VAF 14/41 reads (34%) | called by mutect2, pindel, varscan2
- SRPK2 | c.883_910del p.R295Kfs*20 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- ZNF429 | c.1833T>G p.H611Q | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANO4 | c.1731G>C p.T577= (on ENST00000392977 / NM_001286615.2; = p.T542= on NM_178826.4) | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV100153598, COSV54583713; called by muse, mutect2, varscan2
- CD101 | c.915G>A p.L305= | Silent (SNP) | VAF 14/74 reads (19%) | catalogued as rs754222925, COSV99870126; called by muse, mutect2, varscan2
- CECR2 | c.3576C>A p.G1192= (on ENST00000342247 / NM_001290047.2; = p.G1008= on NM_001290046.1) | Silent (SNP) | VAF 30/114 reads (26%) | catalogued as rs370707590, COSV99378937; called by muse, mutect2, varscan2
- CEP170 | c.3741A>C p.S1247= | Silent (SNP) | VAF 26/332 reads (8%) | catalogued as COSV100317711; called by muse, mutect2
- CLOCK | c.2541G>A p.*847= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100011963; called by muse, mutect2, varscan2
- EPHX1 | c.1213C>T p.L405= | Silent (SNP) | VAF 41/329 reads (12%) | catalogued as COSV99689175; called by muse, varscan2
- GCN1 | c.6360G>A p.L2120= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV100325877; called by muse, mutect2, varscan2
- GFM1 | c.543C>T p.S181= | Silent (SNP) | VAF 98/209 reads (47%) | catalogued as COSV51834471, COSV99963111; called by muse, mutect2, varscan2
- GIMAP8 | c.1527G>T p.R509= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as COSV100217674; called by muse, mutect2, varscan2
- HIP1R | c.135C>T p.P45= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as rs112655537, COSV99459199, COSV99459372; called by muse, mutect2, varscan2
- IPO9 | c.2352G>A p.Q784= | Silent (SNP) | VAF 15/101 reads (15%) | catalogued as COSV100843541, COSV100843542; called by muse, mutect2, varscan2
- LRP1 | c.9891C>T p.N3297= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as COSV99676958; called by muse, mutect2, varscan2
- LY9 | c.1365T>A p.L455= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as COSV99627353; called by muse, mutect2, varscan2
- MBD3L1 | c.6C>A p.A2= | Silent (SNP) | VAF 23/31 reads (74%) | catalogued as COSV99978042; called by muse, mutect2, varscan2
- NCK1 | c.111C>T p.S37= | Silent (SNP) | VAF 14/248 reads (6%) | catalogued as COSV99999807; called by muse, mutect2
- NLRC4 | c.1105C>T p.L369= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100707492, COSV61593854; called by muse, mutect2, varscan2
- OR5T1 | c.678C>T p.V226= | Silent (SNP) | VAF 13/27 reads (48%) | catalogued as rs1565096461, COSV57304663; called by muse, mutect2, varscan2
- PHEX | c.39G>A p.K13= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1186515646, COSV101039979; called by muse, mutect2, varscan2
- SLCO1C1 | c.1833G>A p.L611= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV56875809, COSV99859850; called by muse, mutect2, varscan2
- TSC2 | c.366C>T p.L122= | Silent (SNP) | VAF 54/231 reads (23%) | catalogued as rs1397677711, COSV99555136; ClinVar: likely benign; called by muse, mutect2, varscan2
- VPS33B | c.1389G>C p.V463= | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100325716; called by muse, varscan2
- ZNF687 | c.3105C>T p.F1035= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV99650080; called by muse, mutect2, varscan2
- CDKL1 | c.367-703C>T | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99367822; called by muse, mutect2, varscan2
- CYP2S1 | c.*113C>T | 3'UTR (SNP) | VAF 23/70 reads (33%) | catalogued as rs749556490, COSV59507846; called by muse, mutect2, varscan2
- NALCN | c.2193-5276C>A | Intron (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- TMEM177 | c.-1C>T | 5'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99733709; called by muse, mutect2
